Somatic mutation profile of tumor specimen C3N-01072-02 (aliquot CPT0084140009) from CPTAC case C3N-01072, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 62.9 years (22,957 days).
Specimen C3N-01072-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 002f4254-81ad-400d-8fc3-6f468c02575c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01072-31 (Blood Derived Normal), aliquot CPT0084190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe01d97b-9c74-4f9e-b458-47978d6bace4

The open-access MAF lists 92 somatic variants for this specimen: 69 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 14, Intron 8, Frame Shift Del 4, Frame Shift Ins 2, In Frame Del 1, Nonsense Mutation 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 108/483 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARRDC4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs957086287; called by muse, mutect2, varscan2
- DCLK1 | c.2101C>T p.R701C (on ENST00000360631 / NM_001330072.2; = p.D725= on NM_004734.5) | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV55189268; called by muse, mutect2, varscan2
- DERL1 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs777366277; called by muse, mutect2
- FETUB | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 97/595 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.678); catalogued as rs754740084, COSV54006374; called by muse, mutect2, varscan2
- GADD45G | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99378501; called by muse, mutect2, varscan2
- GON4L | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs766441466; called by mutect2, varscan2
- GPI | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370578920; called by muse, mutect2, varscan2
- NLGN4X | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1051301935, COSV99321667; called by muse, mutect2, varscan2
- NLRP8 | c.2914G>A p.A972T | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.304); catalogued as rs745519828, COSV52591966; called by muse, mutect2, varscan2
- NRK | c.4150C>T p.P1384S | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV54605416; called by muse, mutect2, varscan2
- PARP10 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs782458070, COSV57297523; called by muse, mutect2, varscan2
- RGS9 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52224270; called by muse, mutect2, varscan2
- RYR1 | c.11985C>A p.F3995L | Missense Mutation (SNP) | VAF 238/546 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62104157, COSV62104853; called by muse, mutect2, varscan2
- SFI1 | c.1757A>G p.K586R (on ENST00000400288 / NM_001007467.3; = p.K555R on NM_014775.4) | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1458204697; called by muse, mutect2, varscan2
- SLIT1 | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756326446, COSV56594419; called by muse, mutect2, varscan2
- TLDC2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as rs760931504, COSV99455763; called by muse, mutect2, varscan2
- UGT2B10 | c.1246T>C p.F416L | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs746743089; called by muse, mutect2, varscan2
- WDR26 | c.1199G>A p.R400H (on ENST00000414423 / NM_001379403.1; = p.R300H on NM_025160.7) | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1211461362, COSV99690765; called by muse, mutect2, varscan2
- ZNF214 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs911281102; called by muse, mutect2, varscan2
- ZNF786 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1445416724, COSV60275852; called by muse, mutect2, varscan2
- ACACB | c.1044G>A p.W348* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- APOB | c.5666C>T p.S1889L | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- AQR | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATPAF2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC6 | c.6810dup p.L2271Tfs*17 | Frame Shift Ins (INS) | VAF 40/277 reads (14%) | called by mutect2, pindel, varscan2
- C10orf62 | c.43_55del p.E15Tfs*57 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | called by mutect2, pindel
- COPG1 | c.2186A>C p.K729T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CPLX2 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CTSG | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CWF19L2 | c.453G>C p.R151S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CYP3A43 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FERMT3 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRS2 | c.812T>G p.L271R | Missense Mutation (SNP) | VAF 71/352 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- GALNT16 | c.798T>G p.H266Q | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GK5 | c.1153A>C p.N385H | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GTF2IRD1 | c.2704A>G p.R902G (on ENST00000265755 / NM_016328.3; = p.R887G on NM_005685.4) | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HTRA2 | c.704dup p.T236Dfs*2 | Frame Shift Ins (INS) | VAF 103/599 reads (17%) | called by mutect2, pindel, varscan2
- IGSF10 | c.6104_6125del p.L2035Pfs*17 | Frame Shift Del (DEL) | VAF 75/504 reads (15%) | called by mutect2, pindel
- KCNE3 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNJ10 | c.992A>G p.D331G | Missense Mutation (SNP) | VAF 93/468 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KDM6A | c.335-2A>G p.X112_splice | Splice Site (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- MUC16 | c.31234A>G p.S10412G | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- MYO1G | c.1502A>G p.Q501R | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR2AE1 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PANX1 | c.666_671del p.I223_I224del | In Frame Del (DEL) | VAF 38/183 reads (21%) | called by mutect2, pindel, varscan2
- PGM1 | c.1234A>T p.I412F | Missense Mutation (SNP) | VAF 109/484 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PLA2G4F | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PLCZ1 | c.656del p.L219Pfs*20 | Frame Shift Del (DEL) | VAF 68/372 reads (18%) | called by mutect2, pindel, varscan2
- PRDM16 | c.1489A>T p.S497C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- PRPF38B | c.530G>T p.W177L | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTPRM | c.2351T>A p.M784K | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PXK | c.508A>C p.N170H | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- RANBP6 | c.2597del p.L866Yfs*10 | Frame Shift Del (DEL) | VAF 49/192 reads (26%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A9 | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SNX5 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SPRING1 | c.397T>A p.S133T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SRSF4 | c.1414T>A p.S472T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ST3GAL5 | c.91A>C p.S31R | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by mutect2, varscan2
- TENM2 | c.3225A>C p.R1075S (on ENST00000518659 / NM_001122679.2; = p.R843S on NM_001080428.3) | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TMTC2 | c.2197A>G p.M733V | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TSFM | c.962T>C p.V321A (on ENST00000323833 / NM_001172696.2; = p.V300A on NM_005726.6) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- UBQLN3 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- USHBP1 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- VANGL2 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 93/545 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- VWA5B2 | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF335 | c.1799A>C p.K600T | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF668 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA13 | c.13323G>C p.G4441= | Silent (SNP) | VAF 40/264 reads (15%) | catalogued as COSV68945967; called by muse, mutect2, varscan2
- CPE | c.609A>G p.K203= | Silent (SNP) | VAF 49/217 reads (23%) | called by muse, mutect2, varscan2
- CYP4F2 | c.120C>T p.A40= | Silent (SNP) | VAF 56/190 reads (29%) | catalogued as COSV99171096; called by muse, mutect2, varscan2
- CYTH2 | c.384T>C p.A128= | Silent (SNP) | VAF 98/296 reads (33%) | called by muse, mutect2, varscan2
- DARS1 | c.129A>C p.R43= | Silent (SNP) | VAF 41/186 reads (22%) | called by muse, mutect2, varscan2
- LRP1 | c.3363A>G p.K1121= | Silent (SNP) | VAF 58/274 reads (21%) | called by muse, mutect2, varscan2
- OR4D2 | c.789T>C p.T263= | Silent (SNP) | VAF 122/635 reads (19%) | called by muse, mutect2, varscan2
- RUSC1 | c.2208C>T p.A736= (on ENST00000368352 / NM_001105203.2; = p.A267= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 67/287 reads (23%) | called by muse, mutect2, varscan2
- SOST | c.414C>T p.R138= | Silent (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.810A>G p.K270= | Silent (SNP) | VAF 81/201 reads (40%) | called by muse, mutect2, varscan2
- SYN3 | c.1602G>A p.P534= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs771047148, COSV60509552; called by muse, varscan2
- TSPYL6 | c.540A>T p.I180= | Silent (SNP) | VAF 52/273 reads (19%) | called by muse, mutect2, varscan2
- TTLL7 | c.975C>T p.S325= | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as rs963199827, COSV53088178; called by muse, mutect2, varscan2
- VCX3B | c.273G>A p.P91= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs765180126; called by mutect2, varscan2
- AC005702.1 | chr17:59976715 T>C | 3'Flank (SNP) | VAF 12/69 reads (17%) | called by mutect2, varscan2
- FBXL2 | c.65+19806G>A | Intron (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- GATM | c.70-424T>G | Intron (SNP) | VAF 46/246 reads (19%) | called by muse, mutect2, varscan2
- GRHL3 | c.1694+4353T>G | Intron (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- HUWE1 | c.8206+1072A>C | Intron (SNP) | VAF 85/195 reads (44%) | called by muse, mutect2, varscan2
- MRPS9 | c.652-1045C>A | Intron (SNP) | VAF 45/279 reads (16%) | called by muse, mutect2, varscan2
- RBM5 | c.953+187A>G | Intron (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- USB1 | c.449+9T>G | Intron (SNP) | VAF 54/311 reads (17%) | catalogued as rs758419253; called by muse, mutect2, varscan2
- WDR49 | c.487-6623A>C | Intron (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
